Gene-level copy-number profile of tumor specimen TCGA-2A-A8VX-01A from TCGA case TCGA-2A-A8VX, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.9 years (25,904 days).
Specimen TCGA-2A-A8VX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.9194d904-9ae2-470b-bfd8-a78934b97a0c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2A-A8VX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ba4eb9ce-5a3d-4dbc-b9c6-ff5957a41a99

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 4,360; copy number 2: 53,855; copy number 3: 1,573.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2A-A8VX-01A-11D-A376-01): tumor purity 0.9, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:103,086,000–103,212,799, 2 genes (within-gene range 0–1): GIN1, PPIP5K2.
- chr5:105,922,994–108,382,098, 12 genes (within-gene range 0–1): RNA5SP189, AC027313.1, AC114940.1, AC114940.2, LINC01950, PSMC1P5, EFNA5, AC024587.2, AC024587.1, RN7SL782P, RN7SKP122, FBXL17.
- chr5:111,912,508–112,419,313, 2 genes (within-gene range 0–1): NREP-AS1, EPB41L4A.
- chr5:112,173,570–112,642,483, 8 genes: AC010261.1, AC010261.2, AC104126.1, AC010265.1, EPB41L4A-DT, HMGB3P16, AC137549.1, LINC02200.
- chr6:93,240,020–94,344,962, 8 genes (within-gene range 0–2): EPHA7, AL591519.1, AL356094.2, AL356094.1, AL391336.2, AL391336.1, AL157378.1, AL078595.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,980. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
